National Lung Screening Trial (NLST) participant 218438 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 65 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer.
- T1 (day 415): No screening result: Inadequate Image.
- T2 (day 736): Negative screen, minor abnormalities not suspicious for lung cancer.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,939, study year T5. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: left upper lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: poorly differentiated (G3). Tumour size on pathology: 18 mm. AJCC 6th edition staging: stage IIIB (best stage, from pathologic TNM); clinical T1 N1 M0 (stage IIA); pathologic T4 N2 M0 (stage IIIB). AJCC 7th edition staging: stage IIIA; clinical T1a N1 M0; pathologic T3 N2 M0. Summary stage: regional.
2. Subsequent primary lung cancer, diagnosed day 1,980, study year T5. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Grade: poorly differentiated (G3). Tumour size on pathology: 11 mm. AJCC 6th edition staging: stage IIIB (best stage, from pathologic TNM); pathologic T4 NX M0 (stage IIIB).

Follow-up
Last known free of lung cancer: day 1,939 (for ACRIN participants with lung cancer this field holds the diagnosis date).
